Gene-level copy-number profile of tumor specimen TCGA-63-A5M9-01A from TCGA case TCGA-63-A5M9, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-63-A5M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.b5132f28-0872-42e5-8d61-5ef20fa70937.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5M9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0ab861a8-925c-4923-b4b0-33bc0ab0332b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 1,448; copy number 2: 24,148; copy number 3: 11,596; copy number 4: 12,108; copy number 5: 5,764; copy number 6: 2,136; copy number 7: 803; copy number 8: 440; copy number 9: 132; copy number 10: 239; copy number 11: 437; copy number 12: 351; copy number 13: 92; copy number 14: 22; copy number 29: 1; copy number 32: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5M9-01A-11D-A26L-01): tumor purity 0.6, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:230,327,184–230,412,529, 2 genes: SP140L, AC009949.1.
- chr19:23,304,991–23,395,471, 1 gene (within-gene range 0–3): ZNF91.
- chr19:23,380,317–24,163,425, 28 genes: BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,369 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:11,658,178–108,099,492, 1,760 genes, copy number 5–7 (broad region; genes not listed).
- chr3:131,026,850–131,350,465, 1 gene, copy number 12 (within-gene range 4–12): NEK11.
- chr3:131,325,092–198,222,513, 1,154 genes, copy number 6–14 (broad region; genes not listed).
- chr4:42,892,396–52,097,299, 97 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:52,862,317–58,565,212, 106 genes, copy number 6 (broad region; genes not listed).
- chr5:31,639,131–32,110,932, 1 gene, copy number 6 (within-gene range 2–6): PDZD2.
- chr5:31,725,539–53,094,779, 279 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:60,719,222–88,175,762, 328 genes, copy number 5 (broad region; genes not listed).
- chr6:88,265,158–88,265,511, 1 gene, copy number 5: AL121835.1.
- chr7:2,403,588–15,701,752, 197 genes, copy number 5–11 (within-gene range 3–11) (broad region; genes not listed).
- chr7:16,087,525–35,259,729, 347 genes, copy number 5–10 (broad region; genes not listed).
- chr9:37,588,413–38,068,687, 1 gene, copy number 5 (within-gene range 4–5): AL138752.2.
- chr9:37,650,954–37,746,904, 1 gene, copy number 5 (within-gene range 4–5): FRMPD1.
- chr9:37,753,803–43,045,120, 149 genes, copy number 5 (broad region; genes not listed).
- chr11:24,496,970–50,422,316, 434 genes, copy number 5–7 (broad region; genes not listed).
- chr11:68,683,779–71,252,577, 63 genes, copy number 29–32 (within-gene range 2–32) (broad region; genes not listed).
- chr12:66,767–38,589,812, 864 genes, copy number 5 (broad region; genes not listed).
- chr12:57,797,376–85,342,912, 411 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr14:73,478,484–73,558,947, 1 gene, copy number 5 (within-gene range 2–5): HEATR4.
- chr14:73,517,233–98,927,805, 463 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–24,912,924, 184 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr15:88,803,436–101,933,350, 331 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr16:66,754,640–76,928,169, 364 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:8,797,110–11,969,748, 64 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr19:27,638,483–54,552,256, 1,392 genes, copy number 5–11 (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 589. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
